Somatic mutation profile of tumor specimen MP2PRT-PATISC-TBP1-A (aliquot MP2PRT-PATISC-TBP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATISC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 8.6 years (3,131 days).
Specimen MP2PRT-PATISC-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 690fa90e-8956-42dd-a7e3-54e84ee8b0d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATISC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATISC-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78f6af08-6cdb-416a-ac2e-6a518582c175

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 308/350 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SYNM | c.2230G>A p.V744I | Missense Mutation (SNP) | VAF 30/460 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as rs782783847; called by muse, mutect2
- TRPC4 | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 129/263 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58993518; called by muse, mutect2, varscan2
- USH2A | c.15373C>T p.R5125C | Missense Mutation (SNP) | VAF 140/310 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs771243585, COSV100243162; called by muse, varscan2
- WDFY4 | c.5743C>T p.R1915* | Nonsense Mutation (SNP) | VAF 117/284 reads (41%) | catalogued as rs765553426; called by muse, mutect2, varscan2
- CTNNB1 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 13/383 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- KDM6A | c.116_117dup p.S40Pfs*3 | Frame Shift Ins (INS) | VAF 30/249 reads (12%) | called by mutect2, pindel, varscan2
- MUC12 | c.2952C>A p.S984R (on ENST00000379442; = p.S841R on NM_001164462.1) | Missense Mutation (SNP) | VAF 45/594 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.316); called by muse, mutect2
- FBLN1 | c.84C>T p.D28= | Silent (SNP) | VAF 145/310 reads (47%) | catalogued as rs754024808, COSV53051778; called by muse, mutect2, varscan2
- ITGA3 | c.1596C>T p.A532= | Silent (SNP) | VAF 46/646 reads (7%) | catalogued as rs557710334, COSV50309077; called by muse, mutect2
- RGPD4 | c.36C>T p.V12= | Silent (SNP) | VAF 35/318 reads (11%) | catalogued as rs748859920, COSV61745894; called by muse, mutect2, varscan2
- SPATA7 | c.543C>A p.S181= | Silent (SNP) | VAF 22/501 reads (4%) | catalogued as COSV99248388; called by muse, mutect2
- AL132655.7 | n.47G>A | RNA (SNP) | VAF 18/550 reads (3%) | called by muse, mutect2
